Somatic mutation profile of tumor specimen RC-B5D0-TBP1-A (aliquot RC-B5D0-TBP1-A-1-0-D-A93N-47) from RC case RC-B5D0, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.2 years (29,284 days).
Specimen RC-B5D0-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a623ce76-9f7e-4ad6-b0a3-be41d45326e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5D0-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5D0-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e19063e-8857-44df-98b4-6dfb852f8edf

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRAS1 | c.9054G>A p.W3018* | Nonsense Mutation (SNP) | VAF 11/253 reads (4%) | catalogued as COSV99348490; called by muse, mutect2
- YBX1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.905); catalogued as rs1046707572; called by muse, mutect2, varscan2
- DIAPH1 | c.3167A>G p.Q1056R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by mutect2, varscan2
- GABRG1 | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC18A2 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SORBS1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); called by muse, mutect2
- TMEM143 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- BANK1 | c.720G>A p.R240= | Silent (SNP) | VAF 72/163 reads (44%) | catalogued as rs371674284; called by muse, mutect2, varscan2
- SHROOM4 | c.18G>A p.G6= | Silent (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
